Somatic mutation profile of tumor specimen 0DRHQ4 from CCDI case PBCGLE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Parotid gland; Age at diagnosis: 7.8 years (2,832 days).
Specimen 0DRHQ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28987692-cedf-4824-bb95-96d80296e75c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRHQ2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad528286-e691-4097-8578-21c50a11b267

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 86/1360 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2
- HLA-DMB | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 56/1080 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 34/301 reads (11%) | called by muse, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
